PECGS case C083-000043 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/0a157177-2253-4fc9-9422-b14cde61b77f

Demographics
Sex at birth: female; Age at index: 33 years; Year of birth: 1985; Education level: Some High School or Less.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Cecum; Age at diagnosis: 33.1 years (12,090 days); AJCC clinical stage: Stage IVA; AJCC pathologic stage: Stage IV; Progression or recurrence: no.

Other clinical attributes
- BMI: 21.21.

Exposures
- Alcohol history: No.

Biospecimens (2 samples)
- Sample C083-000043_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000043_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
